Surgical pathology report (de-identified scan), TCGA case TCGA-39-5022, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site MSKCC, specimen TCGA-39-5022-01A (Primary Tumor).

[page 1 of 5]
TCGA-39-5022

Clinical Diagnosis & History:

with RUL nodule. PET positive. FNA squamous cell carcinoma.

Specimens Submitted:

- 1: SP: Right level ten mediastinal lymph node
- 2: SP: Right level eleven mediastinal lymph node
- 3: SP: Right level 11 interlobar lymph node
- 4: SP: Right level eleven mediastinal lymph node
- 5: SP: Right upper lung lobe
- 6: SP: Right level four mediastinal lymph node

DIAGNOSIS:

- 1) LYMPH NODE, RIGHT LEVEL X MEDIASTINUM; EXCISION:
- NO TUMOR SEEN IN ONE LYMPH NODE.
- 2) LYMPH NODE, RIGHT LEVEL XI MEDIASTINUM; EXCISION:
- ONE LYMPH NODE WITH OLD CALCIFIED GRANULOMAS (SEE COMMENT).
- NO TUMOR IS SEEN.

COMMENT: NO MYCOBACTERIA OR FUNGI ARE SEEN ON AFB, FITE OR GMS STAINS.

- 3) LYMPH NODE, RIGHT LEVEL XI INTERLOBAR; EXCISION:
- NO TUMOR IS SEEN IN ONE LYMPH NODE.
- 4) LYMPH NODE, RIGHT LEVEL XI MEDIASTINUM; EXCISION:
- NO TUMOR IS SEEN IN ONE LYMPH NODE.
- 5) LUNG, RIGHT UPPER LOBE; LOBECTOMY:
- SQUAMOUS CELL CARCINOMA, MODERATELY TO POORLY DIFFERENTIATED, OF RIGHT UPPER LOBE.
- THE TUMOR MEASURES 3.7 X 3.2 X 2.5 CM.
- NO VASCULAR INVASION IS IDENTIFIED.
- THE MAINSTEM BRONCHUS IS NOT INVOLVED BY TUMOR.
- THE BRONCHIAL MARGIN IS FREE OF TUMOR.
- THE STAPLED PARENCHYMAL MARGIN IS FREE OF TUMOR.
- THE TUMOR INVADERS THE PLEURA BUT DOES NOT CROSS THE ELASTICA (PO, EVG STAIN PERFORMED).
- THE NON-NEOPLASTIC LUNG SHOWS THE FOLLOWING ABNORMALITIES: EMPHYSEMATOUS CHANGES, FOCAL ATYPICAL ADENOMATOUS HYPERPLASIA (AAH), ORGANIZING PNEUMONIA

** Continued on next page **

[page 2 of 5]
----- Page 2 of 5
AND RESPIRATORY BRONCHIOLITIS.
- NO TUMOR IS SEEN IN 2 PERIBRONCHIAL AND 7 INTRAPARENCHYMAL LYMPH NODES.

6) LYMPH NODE, RIGHT LEVEL IV MEDIASTINUM; EXCISION:
- NO TUMOR IS SEEN IN LYMPH NODE FRAGMENTS.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	AFB	
	PITE	
	GMS	
	EVG	
	EVG	

Gross Description:

1) The specimen is received fresh for frozen section, labeled "Right
Level 10 Mediastinal Lymph Node". It consists of a 0.6 x 0.5 x 0.2 cm lymph
node which is entirely frozen for intraoperative diagnosis.

Summary of Sections:

FSC - frozen section control

2) The specimen is received fresh for frozen section, labeled "Right
Level 11 Mediastinal Lymph Node". It consists of 1.0 x 0.5 x 0.5 cm lymph
node which is entirely frozen for intraoperative diagnosis.

Summary of Sections:

FSC - frozen section control

3). The specimen is received fresh for frozen section consultation labeled,
"Right level 11 interlobar lymph node", and consists of an irregular piece
of tan soft tissue measuring 0.9 x 0.7 x 0.4 cm. The specimen is entirely
frozen.

Summary of sections:

FSC frozen section control

** Continued on next page **

[page 3 of 5]
4) The specimen is received in formalin, labeled, "Right level eleven mediastinal lymph node". It consists of a 1.0 x 0.8 x 0.3 cm anthracotic lymph node which is entirely submitted.

Summary of Sections:
LN - lymph node

5). The specimen is received fresh labeled "Right upper lobe of lung", and consists of a resected lobe of lung measuring 16 x 11 x 3 cm. The pleural surface is pink-tan and smooth. There is a 17 cm staple line identified on the medial aspect of the specimen. The lateral aspect of the specimen shows a 4 x 3 cm area of pleural thickening. This surface is inked black. This area also shows a 3 cm incised area containing three blue silk sutures. The stapled margin, bronchial margin, and vessel margins are shaved and submitted entirely. There are multiple anthracotic peribronchial lymph nodes identified and entirely submitted. On bivalving the specimen, there is a 3.7 x 3.2 x 2.5 cm firm variegated grey-tan tumor nodule underlying the area of pleural thickening. It is abuts the pleura and located 1.9 cm from the bronchial margin and 2.2 cm from the stapled margin. The remainder of the lung parenchyma shows diffuse emphysematous changes, particularly surrounding the tumor. There are multiple intraparenchymal lymph nodes identified and submitted entirely. On complete opening of the bronchus, there is no lesions identified on the mucosa. Representative sections are submitted. A sample of the tumor is given to TPS. The specimen has been photographed.

Summary of sections:
SM-stapled margin
VM-vessel margins
PBN-peribronchial nodes
IPN-intraparenchymal nodes
RS-representative sections of lung parenchyma
T-tumor

6) The specimen is received in formalin, labeled, "Right level four mediastinal lymph node". It consists of three fragments of dark anthracotic lymph nodes with attached fat, measuring 2.5 x 1.5 x 0.9 cm in aggregate. The largest fragment appears to be a single 1.4 cm lymph node. The specimen is bisected and the remaining two fragments are entirely submitted whole.

Summary of Sections:
BN bisected lymph node
SDN single lymph node

** Continued on next page **

[page 4 of 5]
Summary of Sections:

Part 1: SP: Right level ten mediastinal lymph node ()

Block	Sect.	Site	PCs
1		fsc	1

Part 2: SP: Right level eleven mediastinal lymph node ()

Block	Sect.	Site	PCs
1		fsc	1

Part 3: SP: Right level 11 interlobar lymph node ()

Block	Sect.	Site	PCs
1		fsc	1

Part 4: SP: Right level eleven mediastinal lymph node

Block	Sect.	Site	PCs
1		ln	1

Part 5: SP: Right upper lung lobe

Block	Sect.	Site	PCs
2		ipn	2
1		pbn	1
5		xs	5
4		sm	4
6		t	6
1		vm	1

Part 6: SP: Right level four mediastinal lymph node

Block	Sect.	Site	PCs
1		hln	1
1		sln	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: BENIGN. ()
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS: BENIGN. ()
PERMANENT DIAGNOSIS: SAME
- 3) FROZEN SECTION DIAGNOSIS: NEGATIVE LYMPH NODES. ()
PERMANENT DIAGNOSIS: SAME

** Continued on next page **

[page 5 of 5]
**** End of Report ****

Source: NCI Genomic Data Commons file 1dc7aee6-db11-4242-9707-79a93537614c (TCGA-39-5022.76F4D72A-526A-4B52-BA4D-067A81281984.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).